MMRF case MMRF_1380 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/bda1aa13-82d0-4a2b-959a-099f3a7661dd

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 63 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 63.1 years (23,039 days); ISS stage: II; Days to last known disease status: 1,429 days (3.9 years); Days to last follow up: 1,429 days (3.9 years).
   Treatment given: Therapeutic agents: Bortezomib + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 166 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 386 days (1.1 years).
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 106 days; Days to treatment end: 166 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 166 days; Days to treatment end: 387 days (1.1 years).
   Treatment given: Therapeutic agents: Pomalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 178 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -3 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 1160 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.557 mg/dL; Immunoglobulin G 5.62 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 4.47 µg/mL; Lactate Dehydrogenase 3.02 µkat/L; Hemoglobin 6.08 mmol/L; Leukocytes 7.2 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 241 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.38 mmol/L; Albumin 44 g/L; Total Protein 6.7 g/dL; Glucose 6.44 mmol/L.
- Day 78 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 340 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.25 mg/dL; Lactate Dehydrogenase 2.37 µkat/L; Hemoglobin 6.51 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 248 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.23 mmol/L; Albumin 37 g/L; Total Protein 5.5 g/dL; Glucose 6.38 mmol/L.
- Day 169 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 211 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.22 mg/dL; Lactate Dehydrogenase 2.5 µkat/L; Hemoglobin 6.2 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 244 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.28 mmol/L; Albumin 36 g/L; Total Protein 5.5 g/dL; Glucose 5.89 mmol/L.
- Day 253 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 42 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.86 mg/dL; Lactate Dehydrogenase 2.2 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 7.7 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 252 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.33 mmol/L; Albumin 40 g/L; Total Protein 5.9 g/dL; Glucose 5.39 mmol/L.
- Day 366 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 19.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.59 mg/dL; Lactate Dehydrogenase 2.33 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 7.3 ×10⁹/L; Absolute Neutrophil 4.4 ×10⁹/L; Platelets 186 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.38 mmol/L; Albumin 39 g/L; Total Protein 5.8 g/dL; Glucose 5.78 mmol/L.
- Day 435 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 12.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.77 mg/dL; Lactate Dehydrogenase 2.33 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 262 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.35 mmol/L; Albumin 39 g/L; Total Protein 6.7 g/dL; Glucose 6.44 mmol/L.
- Day 540 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 15.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.95 mg/dL; Lactate Dehydrogenase 1.88 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 193 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.3 mmol/L; Albumin 38 g/L; Total Protein 6.3 g/dL; Glucose 4.51 mmol/L.
- Day 645 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 12.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.7 mg/dL; Lactate Dehydrogenase 2.07 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 256 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 2.5 mmol/L; Calcium 2.28 mmol/L; Albumin 37 g/L; Total Protein 6.4 g/dL; Glucose 5.67 mmol/L.
- Day 729 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 13 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.76 mg/dL; Lactate Dehydrogenase 1.8 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 286 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.3 mmol/L; Albumin 36 g/L; Total Protein 6.8 g/dL; Glucose 6.44 mmol/L.
- Day 813 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 10.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.94 mg/dL; Lactate Dehydrogenase 1.8 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 224 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.25 mmol/L; Albumin 37 g/L; Total Protein 6.4 g/dL; Glucose 5.72 mmol/L.
- Day 904 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 10.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.36 mg/dL; Lactate Dehydrogenase 1.65 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 181 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.3 mmol/L; Albumin 37 g/L; Total Protein 6.3 g/dL; Glucose 6.6 mmol/L.
- Day 1,002: Serum Free Immunoglobulin Light Chain, Kappa 10.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.32 mg/dL; Lactate Dehydrogenase 1.83 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 5.4 ×10⁹/L; Platelets 212 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.23 mmol/L; Albumin 37 g/L; Total Protein 6.3 g/dL; Glucose 5.01 mmol/L.
- Day 1,058 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 8.32 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.23 mg/dL; Lactate Dehydrogenase 1.67 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 199 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.4 mmol/L; Albumin 38 g/L; Total Protein 6.8 g/dL; Glucose 5.78 mmol/L.
- Day 1,177: Serum Free Immunoglobulin Light Chain, Kappa 7.42 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.91 mg/dL; Lactate Dehydrogenase 1.97 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 232 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 1.71 mmol/L; Calcium 2.15 mmol/L; Albumin 35 g/L; Total Protein 6.2 g/dL; Glucose 5.5 mmol/L.
- Day 1,240: Serum Free Immunoglobulin Light Chain, Kappa 6.34 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.06 mg/dL; Lactate Dehydrogenase 2.08 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 254 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.35 mmol/L; Albumin 39.8 g/L; Total Protein 6.8 g/dL; Glucose 5.78 mmol/L.
- Day 1,359: Serum Free Immunoglobulin Light Chain, Kappa 5.36 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.93 mg/dL; Lactate Dehydrogenase 1.85 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 275 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.35 mmol/L; Albumin 40 g/L; Total Protein 7 g/dL; Glucose 6.27 mmol/L.
- Day 1,429 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 4.95 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.82 mg/dL; Lactate Dehydrogenase 2.47 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 6.8 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 204 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.38 mmol/L; Albumin 41 g/L; Total Protein 6.8 g/dL; Glucose 5.67 mmol/L.

Other clinical attributes
- Day -3: Weight: 86 kg; Height: 170 cm.

Biospecimens (3 samples)
- Sample MMRF_1380_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -3 days.
- Sample MMRF_1380_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 169 days.
- Sample MMRF_1380_2_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 169 days.
